Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PV, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PV-01A (Primary Tumor).

[page 1 of 4]
ICD-A Discrepancy		☒
Prior Malignant History		☒
Dual/Syn. Primary/Noted		☒

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

year old female with 1.5 cm left thyroid nodule likely PTC by FNA.

Specimens Submitted:

- 1: To rule out left lower parathyroid (fs)
- 2: Tissue near left recurrent laryngeal nerve (fs)
- 3: Thyroid, total thyroidectomy
- 4: Pretracheal lymph node
- 5: Delphian tissue
- 6: Left paratracheal node
- 7: Left paratracheal tissue

DIAGNOSIS:

1. "? left lower parathyroid", biopsy (fs):
- Benign parathyroid gland
2. "Tissue near left recurrent laryngeal nerve", excision (fs):
- One benign lymph node (0/1)
3. Thyroid, total thyroidectomy:
- Tumor Type:
- Papillary carcinoma, classical type
- Histologic Grade:
- Well differentiated
- Mitotic Activity:
- Not identified
- Tumor Necrosis:
- Not identified
- Other Tumor Features:
- Calcification of non-psammoma type
- Tumor Location:
- Left lobe
- Tumor Size:
- Greatest diameter is 3.4 cm.
- Tumor Encapsulation:
- Completely surrounded
- Capsular Invasion:
- Focal invasion
- Blood Vessel Invasion:

1ED-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw
8/31/11

[page 2 of 4]
Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor is less than 1 mm from the inked margin.

Tumor Multicentricity:

Microscopic foci present

One papillary microcarcinoma is identified in right lobe, measuring 1.8 mm in greatest dimension

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

Lymph Nodes:

One benign lymph node is present

4. Pretracheal lymph node, excision:

- One benign lymph node (0/1)

5. Delphian tissue, excision:

- One benign lymph node (0/1)

- Fragment of benign thyroid tissue

6. Left paratracheal node, excision:

- One benign lymph node (0/1)

7. Left paratracheal tissue, excision:

- Two benign lymph nodes (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "To rule out left lower parathyroid" and consists of a nodule measuring 0.3 x 0.3 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2. The specimen is received fresh for frozen section consultation, labeled "tissue near left recurrent laryngeal nerve" and consists of an irregular piece of soft tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3). The specimen is received fresh, labeled "Total thyroid" and consists of a thyroid weighing 27.5 g. The right lobe measures 4.3 x 2.5 x 1.5 cm, the left lobe measures 4.5 x 3.5 x 2.5 cm and the isthmus measures 2.5 x 1.6 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals cystic, papilliferous, well-circumscribed, focally calcified, brown-tan nodule measuring 3.4 x 3.0 x 1.7 cm in the

[page 3 of 4]
left lobe. The nodule is abutting both the anterior and posterior capsule. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS, and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

4. The specimen is received in formalin labeled "pre tracheal lymph node" is a 1.5 x 1.0 x 0.4 cm fibroadipose soft tissue fragment with an embedded lymph node measuring 0.8 cm in greatest dimension. The specimen is submitted in toto.

Summary of sections:

LN-lymph node

5. The specimen is received in formalin labeled "Delphian tissue" is a 2.0 x 1.5 x 0.4 cm tan-pink soft tissue fragment. Specimen is submitted in toto.

Summary of sections:

U-undesignated

6. The specimen is received in formalin labeled "left paratracheal node" is a 0.4 x 0.3 x 0.3 cm lymph node. The specimen is submitted in toto.

Summary of sections:

LN-lymph node

7. Desmin is received fresh labeled "left para tracheal tissue" is a 2.0 x 1.0 x 2.0 cm adipose tissue fragment with an embedded lymph node measuring 0.4 cm in greatest dimension. The specimen is submitted in toto.

Summary of sections:

LN-lymph node

Summary of Sections:

Part 1: To rule out left lower parathyroid (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Tissue near left recurrent laryngeal nerve (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
2	IS	4
5	LL	9
18	N	33
7	RL	13

Part 4: Pretracheal lymph node

Block	Sect. Site	PCs
-------	------------	-----

[page 4 of 4]
1 In 1

Part 5: Delphian tissue

Block	Sect. Site	PCs
1	U	1

Part 6: Left paratracheal node

Block	Sect. Site	PCs
1	LN	1

Part 7: Left paratracheal tissue

Block	Sect. Site	PCs
1	LN	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: To rule out left lower parathyroid (fs): Benign parathyroid tissue.
PERMANENT DIAGNOSIS: same
2. FROZEN SECTION DIAGNOSIS: Tissue near left recurrent laryngeal nerve (fs): Benign lymph node.
PERMANENT DIAGNOSIS: same

Source: NCI Genomic Data Commons file beefacde-cdac-4170-b0e1-79347381ef8d (TCGA-DJ-A2PV.C1CBFF56-4A0E-4A36-AAA2-2A316C62E00E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).